Somatic mutation profile of tumor specimen MP2PRT-PAVTRE-TMP1-A (aliquot MP2PRT-PAVTRE-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVTRE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,276 days).
Specimen MP2PRT-PAVTRE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a06e8fa-a89b-4a58-905d-62f3c9832c35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVTRE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVTRE-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f9bd75f-a59c-42ec-9580-6ba08dbf576d

The open-access MAF lists 22 somatic variants for this specimen: 20 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 15, Frame Shift Ins 3, Silent 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO1 | c.1930C>T p.R644C | Missense Mutation (SNP) | VAF 27/459 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as rs367661774; called by muse, mutect2
- AZIN2 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 118/518 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754794309, COSV53856663; called by muse, mutect2, varscan2
- DMD | c.6596T>A p.L2199Q | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV58938090; called by muse, mutect2
- ERG | c.1121G>A p.R374H (on ENST00000398919 / NM_001243428.1; = p.R350H on NM_004449.4) | Missense Mutation (SNP) | VAF 232/546 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55728243, COSV55731950; called by muse, mutect2, varscan2
- GPRC5B | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 361/827 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754939873; called by muse, mutect2, varscan2
- IQCH | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1010034421, COSV60050841; called by muse, mutect2
- PCDHB10 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 26/660 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); catalogued as rs781947513, COSV53377622; called by muse, mutect2
- PCDHGA7 | c.1070C>A p.P357H | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.852); catalogued as COSV99542378, COSV99544169; called by muse, mutect2
- SYDE1 | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 72/919 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs776276724; called by muse, mutect2
- ZEB2 | c.3214C>A p.Q1072K | Missense Mutation (SNP) | VAF 44/714 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV57951889; called by muse, mutect2
- ZNF226 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as rs1429179481; called by muse, mutect2, varscan2
- ADCY1 | c.2711T>C p.F904S | Missense Mutation (SNP) | VAF 33/352 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EDIL3 | c.519A>C p.Q173H | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MAU2 | c.404A>T p.Q135L | Missense Mutation (SNP) | VAF 115/524 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- MEI4 | c.1030A>T p.K344* | Nonsense Mutation (SNP) | VAF 49/191 reads (26%) | called by muse, mutect2, varscan2
- MGA | c.1994_1995del p.F665Cfs*4 | Frame Shift Del (DEL) | VAF 45/154 reads (29%) | called by mutect2, pindel, varscan2
- MGA | c.3449_3451delinsGACCCCCCACACTGGGT p.P1150Rfs*17 | Frame Shift Ins (INS) | VAF 45/139 reads (32%) | called by pindel, varscan2*
- PEAR1 | c.2287G>A p.V763M | Missense Mutation (SNP) | VAF 177/519 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- POLE | c.1692_1693insCCGCGGAGGACCT p.A565Pfs*8 | Frame Shift Ins (INS) | VAF 48/484 reads (10%) | called by mutect2, pindel
- RGS19 | c.167_168dup p.R57Gfs*39 | Frame Shift Ins (INS) | VAF 236/722 reads (33%) | called by mutect2, pindel, varscan2
- CBX5 | c.180T>C p.P60= | Silent (SNP) | VAF 49/165 reads (30%) | catalogued as rs1444788641; called by muse, mutect2, varscan2
- GRIN3B | c.1386G>A p.A462= | Silent (SNP) | VAF 51/886 reads (6%) | catalogued as rs1175293732; called by muse, mutect2
